CCDI case PBBNBU — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/54c70f7c-48ea-438d-823a-8518d96c002f

Demographics
Sex at birth: female; Race: native hawaiian or other pacific islander.

Diagnoses (1)
1. Spindle cell sarcoma: ICD-O-3 morphology code: 8801/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 14.5 years (5,286 days).

Biospecimens (3 samples)
- Sample 0DCXAB: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DCXAH: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DCXAT: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
